Surgical pathology report (de-identified scan), TCGA case TCGA-A2-A4S3, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Walter Reed, specimen TCGA-A2-A4S3-01A (Primary Tumor).

[page 1 of 3]
Name: [REDACTED] Age/Sex: [REDACTED] /F Location: [REDACTED]
Acct#: [REDACTED] Unit#: [REDACTED] Status: [REDACTED] Room/Bed: [REDACTED]
Reg: [REDACTED] Disch: [REDACTED] Att Dr: [REDACTED], M.D.

Specimen: Received: Status: Req#: [REDACTED]
Collected: Sp type: SURGICAL P
Subm Dr: [REDACTED], M.D.

PREOPERATIVE DIAGNOSIS

LEFT BREAST CANCER WITH POSITIVE NODE

OPERATION PERFORMED

DATE:

DOCTOR(S):

PROCEDURE: MASTECTOMY MODIFIED RADICAL/TOTAL MASTECTOMY

TISSUE REMOVED

- A. RIGHT BREAST @
- B. LEFT BREAST AND AXILLARY CONTENTS
- C. HIGHEST LEFT AXILLARY LYMPH NODE

1C0-0-3
carcinoma, infiltrating duct, NOS 8500/3
Site: breast, NOS C50.9 lw
10/24/12

GROSS DESCRIPTION

RECEIVED IN 3 PARTS.

PART A RECEIVED LABELED [REDACTED] RIGHT BREAST STITCH AT 12 O'CLOCK, IS A 1435.5 GRAM MASTECTOMY. SECTIONING REVEALS THE MAJORITY OF THE SPECIMEN TO CONSIST OF BLAND YELLOW FATTY TISSUE WITH FINE FIBROUS BANDS. CENTRALLY, THE FIBROUS BANDS BECOME BROADER BUT NO MASSES ARE IDENTIFIED. REPRESENTATIVE SECTIONS ARE SUBMITTED AS FOLLOWS: A1--NIPPLE, A2--CENTRAL DEEP MARGIN, A3 AND 4--UPPER INNER QUADRANT, A5 AND 6--UPPER OUTER QUADRANT, A7 AND 8--LOWER OUTER QUADRANT, A9 AND 10--LOWER INNER QUADRANT.

NOTE: MIRROR IMAGE SECTIONS FROM THE NIPPLE AND RANDOM QUADRANT SECTIONS (A1, A3, A5, A7, AND A9) ARE SUBMITTED PER CLINICAL BREAST CARE PROJECT RESEARCH PROTOCOL, FROZEN IN

PART B RECEIVED LABELED [REDACTED], LEFT BREAST AND AXILLARY CONTENTS DOUBLE STITCH AT 12 O'CLOCK LONG STITCH AT AXILLARY CONTENTS, IS A 2170 GRAM LEFT MODIFIED RADICAL MASTECTOMY SPECIMEN WHICH MEASURES 34.5 CM FROM MEDIAL TO LATERAL, 24 CM FROM SUPERIOR TO INFERIOR, AND UP TO 6.5 CM FROM ANTERIOR TO THE DEEP MARGIN. THE NIPPLE IS UNREMARKABLE WITHIN A 30 X 15 CM SKIN ELLIPSE. A SUTURE DENOTES 12 O'CLOCK. THERE IS A MASS PALPABLE AT THE 3 O'CLOCK AND 12 O'CLOCK POSITIONS AND A MASS PALPABLE TOWARDS THE AXILLARY TAIL. THE ANTERIOR MARGIN IS MARKED WITH BLUE INK, THE DEEP IS MARKED WITH BLACK. THE AXILLARY TAIL IS REMOVED AND WHERE IT IS CUT FROM THE MASTECTOMY SPECIMEN, THE MARGIN IS MARKED WITH RED INK

[page 2 of 3]
Patient: [REDACTED]

(Continued)

Specimen:

Received:

Status:

Req#: [REDACTED]

Collected:

Sp type: SURGICAL P

Subm Dr:

M.D.

GROSS DESCRIPTION

(Continued)

AND DOES NOT REPRESENT TRUE MARGIN. IN THE LOW AXILLARY TAIL, THERE IS A 3.5 X 3.2 X 2.3 CM LYMPH NODE. A RIBBON CLIP IS IDENTIFIED. A CENTRAL CROSS-SECTION IS SUBMITTED IN B2 AND 3. SECTIONING REVEALS 4 MASSES WITHIN THE UPPER OUTER QUADRANT BETWEEN 300 AND 1200. THE MOST LATERAL AT 3 O'CLOCK IS A SMALL IRREGULAR AREA MEASURING 1 X 0.8 X 0.6 CM. THIS IS 0.5 CM FROM THE DEEP MARGIN AND IS DEEP TO THE LATERAL EDGE OF THE SECOND MASS GROSSLY SEPARATED BY 2 CM. THE SECOND MASS MEASURES 3.5 X 2.7 X 3.5 CM FROM MEDIAL TO LATERAL. THE SECOND MASS IS INFERIOR TO THE THIRD AND FOURTH MASSES WHICH ARE AT 12 O'CLOCK. THE DEEPEST IS A 1.6 X 1.3 X 1 CM MASS GROSSLY 2 CM DEEP TO THE FOURTH MASS WHICH MEASURES 4 CM FROM SUPERIOR TO INFERIOR, 3 CM FROM ANTERIOR TO POSTERIOR, AND 4 CM FROM MEDIAL TO LATERAL. THE DEEPEST OF THESE LESIONS IS 2 CM FROM THE DEEP MARGIN. THIS LAST LESION IS 1.5 CM BENEATH THE SKIN. THE REMAINING BREAST TISSUE CONSISTS OF BLAND YELLOW FATTY TISSUE. THE 2 LARGEST MASSES, ALTHOUGH GROSSLY SEPARATE, APPEAR TO ABUT EACH OTHER AND ANTERIOR TO THIS AREA IS AN ADDITIONAL 0.6 CM IN DIAMETER MASS (B4). A RIBBON CLIP IS FOUND AT THE INFERIOR EDGE OF MASS 2. A COIL CLIP IS ALSO IDENTIFIED WITHIN MASS 2. SECTIONS ARE SUBMITTED AS FOLLOWS: B1--NIPPLE, B2 AND 3--LOW AXILLARY LYMPH NODE, B4--SMALL LESION ANTERIOR TO THE AREA OF THE 2 LARGER MASSES, B5--THE TISSUE ADJACENT MEDIAL TO THE SECOND-DESCRIBED MASS AND INFERIOR TO THE FOURTH-DESCRIBED MASS, B6--DEEP MARGIN TO MASS 1 AND 2, B7--MASS 1, B8--AREA BETWEEN MASS 1 AND MASS 2, B9 AND 10--FULL CROSS-SECTION OF MASS 2, B11--THE MOST MEDIAL EDGE OF MASS 2, B12--THE MOST LATERAL EDGE OF TUMOR 2, B13--DEEP MARGIN TO MASS 3 AND 4, B14--TISSUE BETWEEN MASS 3 AND MASS 4 WITH THE RED INK ALONG THE EDGE ADJACENT TO MASS 4, B15--MASS 3 WITH ADJACENT SMALL NODULE, B16 THROUGH 18--A LONGITUDINAL SECTION THROUGH MASS 4 FROM SUPERIOR TO INFERIOR, B19--THE MOST LATERAL AREA OF MASS 4, B20--THE MOST MEDIAL ASPECT OF MASS 4, B21--THE ANTERIOR MARGIN TO MASS 4 SUPERIOR TO THE SKIN ELLIPSE.

NOTE: SECTIONS ARE SUBMITTED FROZEN IN PER THE CLINICAL BREAST CARE PROJECT RESEARCH PROTOCOL WITH A MIRROR IMAGE OF THE NIPPLE AND RANDOM QUADRANT SECTIONS (B1 AND B22-B25). IN ADDITION, SECTIONS OF THE LARGE LYMPH NODE #1 ARE SUBMITTED AS P1-2 WITH TISSUE ALSO FROZEN IN TISSUE FROM THE FIRST TUMOR (B7) IS SUBMITTED AS P3, OF THE SECOND TUMOR AS P4-5 AND P10 WITH TISSUE ALSO FROZEN IN OF THE THIRD TUMOR AS P6 AND THE FOURTH TUMOR AS P7 THROUGH P9 WITH ADDITIONAL TISSUE FROZEN IN TISSUE TAKEN BETWEEN MASS 3 AND 4 (B14) IS SUBMITTED AS P11.

FURTHER EXAMINATION OF THE AXILLARY TAIL REVEALS 6 ADDITIONAL LYMPH NODES, ONE OF WHICH IS GROSSLY POSITIVE. THESE ARE SUBMITTED AS FOLLOWS: B26--GROSSLY POSITIVE NODE BISECTED, B27--1 NODE BISECTED, B28--1 VERY SMALL NODE BISECTED, B29--2 NODES, B30 THROUGH B32--1 NODE

[page 3 of 3]
(Continued)

Req# :

Sp type: SURGICAL P

M.D.

GROSS DESCRIPTION

(Continued)

TOTAL, SECTIONED.

PART C RECEIVED LABELED [REDACTED] HIGHEST LEFT AXILLARY
NODE, ARE 4 FRAGMENTS OF YELLOW FATTY TISSUE TOGETHER MEASURING 16 X 2.8
X 1.2 CM. THIS IS EXAMINED FOR LYMPH NODES OF WHICH 6 ARE IDENTIFIED.
THESE ARE SUBMITTED AS FOLLOWS: C1--1 NODE SECTIONED, C2--4 NODES,
C3--1 NODE BISECTED.

COMMENT: THIS CASE IS IN COMPLIANCE WITH CAP/ASCO GUIDELINE OF 6-48 HOURS FORMALIN FIXATION TIME.

PATH PROCEDURES

PROCEDURES:

88305, 88307, 88309, A BLK/10, B BLK/32, C BLK/3

FINAL DIAGNOSIS

PART A RIGHT BREAST, MASTECTOMY: BREAST TISSUE WITH FIBROCYSTIC CHANGE WITH DUCT HYPERPLASIA OF THE USUAL TYPE, APOCRINE METAPLASIA AND CYST FORMATION. CALCIFICATIONS ARE PRESENT. NO EVIDENCE OF ATYPIA OR MALIGNANCY. NIPPLE WITH HYPERKERATOSIS OF THE EPIDERMIS.

FCC
IDH-2 AM
Ca⁺⁺

PART B LEFT BREAST, MODIFIED RADICAL MASTECTOMY:

1. MULTICENTRIC IN SITU AND INFILTRATING DUCT CARCINOMAS GRADE 3 WITH NUCLEAR GRADE 2 AND HIGH MITOTIC INDEX.
2. MULTIPLE INVASIVE TUMORS ARE PRESENT MEASURING 4, 10, 12, 35 AND 40 MM IN GREATEST DIMENSION.
3. LYMPHATIC INVASION IS PRESENT.
4. METASTATIC CARCINOMA TO 2 OF 7 AXILLARY LYMPH NODES.
5. THE POSTERIOR AND ANTERIOR MARGINS AND NIPPLE ARE FREE OF NEOPLASM.
6. FIBROCYSTIC CHANGE.

1 DC 3/2/3 X 5
multicentric
4cm 3.5cm 1.2cm 1cm
4mm

(+) LVI
2/7 LN

① marg

FCC

$\frac{0}{8}LN$

PART C HIGHEST AXILLARY LEFT LYMPH NODES: LYMPH NODES (8), NEGATIVE FOR TUMOR.

	Yes	No
Discrepancy	/	/
Noted	/	/
QUANTIFIED	/	/
Not Rejected	/	/

Source: NCI Genomic Data Commons file 3ec174bd-7808-4b8c-a0fe-143c3fa0c37d (TCGA-A2-A4S3.351D8E38-6E04-4F54-8CB1-975AEB7DB552.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).